Gene-level copy-number profile of tumor specimen TCGA-02-0087-01A from TCGA case TCGA-02-0087, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 27.9 years (10,185 days).
Specimen TCGA-02-0087-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.6964f433-da0a-43d3-8b8f-c32050a42b2c.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 4,909 have no estimate.
https://portal.gdc.cancer.gov/files/5f071ec7-513d-46a3-b410-e8158f9de06b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,398; copy number 2: 50,791; copy number 3: 3,267; copy number 4: 24; copy number 5: 137; copy number 6: 97.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0087-01): tumor purity 0.72, ploidy 2.07, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 234 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:12,653,138–31,928,876, 234 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,398. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
